Somatic mutation profile of tumor specimen MMRF_1879_1_BM_CD138pos (aliquot MMRF_1879_1_BM_CD138pos_T1_KBS5U_L05786) from MMRF case MMRF_1879, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.0 years (25,572 days).
Specimen MMRF_1879_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c16c8f80-91ed-46dc-882f-c95aa60f00bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1879_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1879_1_PB_Whole_C3_KBS5U_L05807; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7d9d18a1-9e91-487a-a191-be938b18bbf6

The open-access MAF lists 68 somatic variants for this specimen: 27 protein-altering or splice-affecting, 7 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 25, Missense Mutation 24, Silent 7, Intron 5, 5'Flank 2, Splice Region 1, Frame Shift Del 1, Frame Shift Ins 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GRIN2B | c.99dup p.S34Qfs*25 | Frame Shift Ins (INS) | VAF 61/162 reads (38%) | catalogued as rs398122823; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- APBB3 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1199366499; called by muse, mutect2, varscan2
- DUSP2 | c.607C>G p.L203V | Missense Mutation (SNP) | VAF 80/140 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV56620536; called by muse, mutect2, varscan2
- IGHV2-70 | c.275A>G p.K92R | Missense Mutation (SNP) | VAF 46/50 reads (92%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as rs778628138; called by muse, varscan2
- IGHV2-70 | c.122G>T p.C41F | Missense Mutation (SNP) | VAF 43/46 reads (93%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs369592881; called by muse, varscan2
- IGKV2-24 | c.142A>G p.S48G | Missense Mutation (SNP) | VAF 79/165 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.404); catalogued as rs1420633226; called by muse, mutect2, varscan2
- KSR2 | c.643A>T p.T215S | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as CM1311357; called by muse, mutect2, varscan2
- LUZP1 | c.2575G>C p.E859Q | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.623); catalogued as COSV56500678; called by muse, mutect2, varscan2
- MYLK | c.2086G>A p.E696K | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.784); catalogued as rs769548990; called by muse, mutect2, varscan2
- PLAG1 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1271939109, COSV100388157, COSV57609038; called by muse, mutect2
- PRDM8 | c.1786G>A p.A596T | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.461); catalogued as rs765278121; called by muse, mutect2, varscan2
- TINAGL1 | c.-15-8C>T | Splice Region (SNP) | VAF 17/44 reads (39%) | catalogued as rs1385598717; called by muse, mutect2, varscan2
- ADAMTS5 | c.1286C>T p.T429I | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- APBB1 | c.1744C>T p.H582Y | Missense Mutation (SNP) | VAF 63/124 reads (51%) | SIFT tolerated (1); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- EPS8L3 | c.818del p.N273Tfs*33 | Frame Shift Del (DEL) | VAF 50/103 reads (49%) | called by mutect2, varscan2
- HSPA9 | c.663T>A p.N221K | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- ISG20 | c.233T>C p.L78P | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- JAKMIP2 | c.1704C>A p.H568Q | Missense Mutation (SNP) | VAF 7/196 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.009); called by muse, mutect2
- OR5B2 | c.370G>T p.V124L | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- PRKG1 | c.1241A>G p.D414G | Missense Mutation (SNP) | VAF 7/175 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2
- S100A11 | c.181G>C p.D61H | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- SAMD4B | c.452A>G p.E151G | Missense Mutation (SNP) | VAF 72/156 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- SSC5D | c.2896A>G p.T966A | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- SULT1E1 | c.334C>T p.L112F | Missense Mutation (SNP) | VAF 60/130 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SYNE1 | c.24578G>C p.R8193P (on ENST00000367255 / NM_182961.4; = p.R8122P on NM_033071.3) | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- SYNRG | c.2801G>C p.G934A | Missense Mutation (SNP) | VAF 104/188 reads (55%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZDHHC3 | c.845G>T p.S282I (on ENST00000424952 / NM_001135179.2; = p.S310I on NM_016598.3) | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2
- ANK1 | c.1524C>T p.H508= | Silent (SNP) | VAF 18/46 reads (39%) | called by muse, mutect2, varscan2
- BDNF | c.417C>T p.S139= | Silent (SNP) | VAF 14/212 reads (7%) | catalogued as rs760274076, COSV100151996; ClinVar: likely benign; called by muse, mutect2
- ERBB4 | c.795C>G p.T265= | Silent (SNP) | VAF 83/185 reads (45%) | catalogued as COSV53498128, COSV53561202; called by muse, mutect2, varscan2
- F5 | c.2286T>G p.T762= | Silent (SNP) | VAF 126/230 reads (55%) | called by muse, mutect2, varscan2
- LMOD1 | c.336C>G p.A112= | Silent (SNP) | VAF 79/186 reads (42%) | called by muse, mutect2, varscan2
- MFSD12 | c.882C>T p.S294= | Silent (SNP) | VAF 24/75 reads (32%) | called by muse, mutect2, varscan2
- PERM1 | c.2082G>T p.G694= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2, varscan2
- ABCC13 | n.484T>G | RNA (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- ACADSB | c.*982A>C | 3'UTR (SNP) | VAF 62/116 reads (53%) | called by muse, mutect2, varscan2
- ACTR3 | c.*4691A>G | 3'UTR (SNP) | VAF 38/71 reads (54%) | catalogued as rs1029999469; called by muse, mutect2, varscan2
- ALDH1B1 | c.*291T>A | 3'UTR (SNP) | VAF 29/74 reads (39%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021255 C>T | 5'Flank (SNP) | VAF 61/123 reads (50%) | catalogued as rs184586185; called by muse, mutect2, varscan2
- CAMK2N1 | c.*517dup | 3'UTR (INS) | VAF 31/67 reads (46%) | catalogued as rs1344011758; called by mutect2, varscan2
- CBX1 | c.*460A>C | 3'UTR (SNP) | VAF 152/349 reads (44%) | called by muse, mutect2, varscan2
- CD8B | c.*573G>C | 3'UTR (SNP) | VAF 10/285 reads (4%) | called by muse, mutect2
- DPPA4 | c.680-81G>C | Intron (SNP) | VAF 5/109 reads (5%) | called by muse, mutect2
- EDIL3 | c.*2438A>G | 3'UTR (SNP) | VAF 21/52 reads (40%) | called by muse, mutect2, varscan2
- EDIL3 | c.*310T>G | 3'UTR (SNP) | VAF 56/111 reads (50%) | called by muse, mutect2, varscan2
- EFCAB14 | c.*720T>G | 3'UTR (SNP) | VAF 35/67 reads (52%) | called by muse, mutect2, varscan2
- FAM122B | c.*2100G>C | 3'UTR (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
- GALC | c.*385G>C | 3'UTR (SNP) | VAF 44/94 reads (47%) | called by muse, mutect2, varscan2
- GPR52 | c.*20C>G | 3'UTR (SNP) | VAF 11/246 reads (4%) | called by muse, mutect2
- L1TD1 | c.*263A>G | 3'UTR (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- MYO1E | c.*2441dup | 3'UTR (INS) | VAF 17/42 reads (40%) | called by mutect2, varscan2
- NETO1 | c.469+24447T>G | Intron (SNP) | VAF 79/157 reads (50%) | called by muse, mutect2, varscan2
- PHYHIPL | c.106+342T>C | Intron (SNP) | VAF 42/114 reads (37%) | called by muse, varscan2
- PSD2 | c.*1194C>T | 3'UTR (SNP) | VAF 47/108 reads (44%) | called by muse, mutect2, varscan2
- RALGAPA2 | c.*3625A>G | 3'UTR (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- RPLP0 | c.54+573T>G | Intron (SNP) | VAF 76/179 reads (42%) | called by muse, mutect2, varscan2
- RRM1 | c.*353A>C | 3'UTR (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2
- SEC61A1 | chr3:128051796 C>T | 5'Flank (SNP) | VAF 46/200 reads (23%) | called by muse, mutect2, varscan2
- SMTNL2 | c.*574A>G | 3'UTR (SNP) | VAF 58/95 reads (61%) | called by muse, mutect2, varscan2
- SSR1 | c.*5135_*5136del | 3'UTR (DEL) | VAF 13/70 reads (19%) | called by pindel, varscan2
- ST13 | c.*1615del | 3'UTR (DEL) | VAF 75/185 reads (41%) | called by mutect2, pindel, varscan2
- TENM4 | c.*3743C>A | 3'UTR (SNP) | VAF 7/149 reads (5%) | called by muse, mutect2
- TMSB4Y | c.-429C>T | 5'UTR (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2
- TRAT1 | c.*1046A>G | 3'UTR (SNP) | VAF 27/53 reads (51%) | called by muse, mutect2, varscan2
- ZFPM2 | c.*419G>T | 3'UTR (SNP) | VAF 33/55 reads (60%) | catalogued as COSV65872375; called by muse, mutect2, varscan2
- ZNF462 | c.*2425C>T | 3'UTR (SNP) | VAF 30/84 reads (36%) | called by muse, mutect2, varscan2
- ZNF638 | c.5871+51A>G | Intron (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- ZNF667 | c.*68T>C | 3'UTR (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2
